Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A5TW, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A5TW-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

Astrocystoma, anaplastic 940113
Site ^{C6CF} Supratentorial ^{NAS} C71.2
path ^B Brain, frontal lobe C71.1
gn 4/18/13

Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age: Location: Received:
Gender: F Acct: Reported:
Physician(s):
Phy Location:

Clinical History

A -year-old woman presents with seizures. Radiology imaging demonstrates a mass in the right frontal lobe, extension into the corpus callosum, extensive mass effect, and midline shift. Peripheral areas of contrast-enhancement are also noted.

Operative Diagnoses

Operation / Specimen

- A: Brain, right frontal, biopsy
- B: Brain, right frontal - deep, biopsy
- C: Brain, right frontal tumor, excision biopsy
- D: Brain, right front - deep tumor excision biopsy
- E: Brain, right frontal tumor, excision biopsy

Pathologic Diagnosis

A, B, C, D, E. Brain, right frontal, craniotomy:

1. Diffuse astrocytoma, consistent with anaplastic astrocytoma, WHO grade 3
2. Negative for codeletion of chromosomal arms 1p and 19q
3. Positive for mutant IDH1-R132H protein by immunostain
4. Ki-67/ MIB-1 proliferation index: up to approximately 10%

See comment.

Comment

This diffuse astrocytoma has readily identifiable mitoses, consistent with anaplastic astrocytoma, WHO grade 3.

Abnormal blood vessels and karyorrhectic nuclei are also identified. However, there is no definite microvascular proliferation and no foci of tumor necrosis.

Pre-operative radiology imaging studies report nodular areas of contrast-enhancement in the periphery of this

neoplasm. The possibility of these biopsies representing peripheral regions of a glioblastoma cannot be excluded.

The histological findings may be correlated with clinical and radiology imaging features for the final clinicopathological interpretation.

Electronically Signed Out

Surgical Pathology

Page 2 of 4

Consultant: Senior Staff Pathologist
Senior Staff Pathologist

Procedures/Addenda

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: Date Reported:

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S552, D1S468, D1S1612, D1S496, D19S219, D19S606 and D19S1182

Results-Comments

[page 2 of 3]
Testing performed on DNA extracted from tumor paraffin block from a

(A2). DNA extracted

corresponding blood specimen was used as a normal reference control.

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and

D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and

D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26

nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of

interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or

otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the

typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

Senior Staff Pathologist

Intra-Operative Consultation

A. Brain, right frontal, biopsy: Diffuse glioma, favor high histological grade. (1 block)

Cytological smears and frozen sections performed at and results reported to the Physician of

Record on

B. Brain, right frontal - deep, biopsy: Diffuse glioma, favor high histological grade. (1 block)

Cytological smears performed at and results reported to the Physician of Record on

Staff Pathologist

Surgical Pathology

Page 3 of 4

Gross Description

A. Brain, right frontal, biopsy:

FIXATIVE: None

GENERAL: A 2 x 1 x 1 cm portion of tan-grey to pink, soft brain tissue, submitted for intraoperative evaluation.

Representatives are submitted for cytological preparations and frozen sections.

SECTIONS: A1 - frozen section remnant; A2 - A3 - unfrozen tissue, entirely submitted.

B. Brain, right frontal - deep, biopsy:

FIXATIVE: None

[page 3 of 3]
GENERAL: A 2 x 1 x 0.5 cm portion of grey-pink, soft brain tissue, submitted for intraoperative evaluation.

Representatives are submitted for cytological preparations.

SECTIONS: B1 - remainder, entirely submitted.

C. Brain, right frontal tumor, excision biopsy:

CONTAINER LABEL: 3 right frontal tumor. FIXATIVE: formalin

GENERAL: A 2.6 x 1.8 x 0.8 cm aggregate of pink, soft brain tissue.

SECTIONS: C1 - C2 - entirely submitted

D. Brain, right front - deep tumor excision biopsy:

CONTAINER LABEL: deep right frontal tumor. FIXATIVE: formalin

GENERAL: A 0.8 x 0.4 x 0.2 cm aggregate of pale tan soft brain tissue.

SECTIONS: D1 - entirely submitted

E. Brain, right frontal tumor, excision biopsy:

CONTAINER LABEL: 5 right frontal tumor. FIXATIVE: formalin

GENERAL: A 1.8 x 1.3 x 0.3 cm aggregate of gray white soft brain tissue.

SECTIONS: E1 - entirely submitted

Microscopic Description

The frozen section diagnosis is confirmed on the permanent sections.

ICD-9(s): 191.1 191.1

Billing Fee Code(s):

Histo Data

Part A: Brain, right frontal, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

FS H&E x 1 1

H&E x 1 1

TPS H&E x 1 1

H&E x 1 2

IDH1-sld x 1 2 no trim please

LOH-curfs x 1 2 no trim please

H&E x 1 3

Part B: Brain, right frontal - deep, biopsy

Taken: Received:

Surgical Pathology

Source: NCI Genomic Data Commons file 3f73e782-661d-467b-9659-364f37c7944d (TCGA-DU-A5TW.CE930C5F-0F10-4CC9-AF72-C38273BEF1E4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).